Somatic mutation profile of tumor specimen TCGA-BA-6873-01A (aliquot TCGA-BA-6873-01A-11D-1870-08) from TCGA case TCGA-BA-6873, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 28.8 years (10,512 days).
Specimen TCGA-BA-6873-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aba4881a-32f4-4ca5-9cf4-1481d205df9e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BA-6873-10A (Blood Derived Normal), aliquot TCGA-BA-6873-10A-01D-1870-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32b2fbfa-1c18-4b22-a361-d7d6b19ba8e8

The open-access MAF lists 70 somatic variants for this specimen: 55 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 14, Nonsense Mutation 4, Frame Shift Del 3, Frame Shift Ins 2, Nonstop Mutation 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 30/41 reads (73%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.578A>T p.H193L | Missense Mutation (SNP) | VAF 14/44 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA13 | c.4939C>T p.H1647Y | Missense Mutation (SNP) | VAF 70/225 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101330121; called by muse, mutect2, varscan2
- AC011462.1 | c.526G>A p.V176M | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.234); catalogued as rs750226738, COSV54197735; called by muse, mutect2, varscan2
- ASIC1 | c.1528G>A p.A510T | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as COSV99948157; called by muse, mutect2
- ATP2A3 | c.631G>A p.G211S | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV99989439; called by muse, mutect2, varscan2
- BEST3 | c.1226G>C p.R409T | Missense Mutation (SNP) | VAF 69/185 reads (37%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV100437882; called by muse, mutect2, varscan2
- BTNL8 | c.114C>A p.F38L | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as COSV99180529; called by muse, mutect2, varscan2
- CACNA1F | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as rs782518630, COSV100545139; called by muse, mutect2, varscan2
- CASP8 | c.202C>T p.R68* | Nonsense Mutation (SNP) | VAF 16/69 reads (23%) | catalogued as rs777784105, COSV51846869; called by muse, mutect2, varscan2
- CCAR1 | c.2260G>C p.D754H | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56268463, COSV99771233; called by muse, mutect2, varscan2
- CEP72 | c.953C>G p.S318* | Nonsense Mutation (SNP) | VAF 16/136 reads (12%) | catalogued as COSV99374831, COSV99375085; called by muse, mutect2, varscan2
- CIP2A | c.973C>A p.P325T | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV55417170, COSV99843045; called by muse, mutect2, varscan2
- CSMD1 | c.995A>G p.H332R | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.769); catalogued as rs371767824; called by muse, mutect2, varscan2
- CSMD3 | c.10877C>A p.T3626K (on ENST00000297405 / NM_001363185.1; = p.T3457K on NM_052900.3) | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99841242; called by muse, mutect2, varscan2
- DCT | c.1078A>G p.T360A | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0.021); catalogued as COSV100986262; called by muse, mutect2, varscan2
- DHX29 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 49/231 reads (21%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV99287487; called by muse, mutect2, varscan2
- ENPEP | c.1675C>T p.R559C | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs544907084, COSV54453278; called by muse, mutect2, varscan2
- EPHA2 | c.1393C>T p.R465* | Nonsense Mutation (SNP) | VAF 50/93 reads (54%) | catalogued as rs1289700800, COSV64452597; called by muse, mutect2, varscan2
- FRMPD4 | c.3911T>G p.F1304C | Missense Mutation (SNP) | VAF 89/160 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV101043562; called by muse, mutect2, varscan2
- GALNT17 | c.858G>T p.Q286H | Missense Mutation (SNP) | VAF 37/184 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.905); catalogued as COSV100354891; called by muse, mutect2, varscan2
- GPR155 | c.2330C>T p.S777F | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0.305); catalogued as COSV99790081; called by muse, mutect2, varscan2
- GPR162 | c.1283C>T p.S428F (on ENST00000311268 / NM_019858.2; = p.S144F on NM_014449.2) | Missense Mutation (SNP) | VAF 97/251 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.221); catalogued as rs782312229, COSV99301473; called by muse, mutect2, varscan2
- HELLS | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99492241; called by muse, mutect2, varscan2
- HHIPL2 | c.2096G>A p.R699K | Missense Mutation (SNP) | VAF 118/423 reads (28%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as COSV100596986; called by muse, mutect2, varscan2
- HOXD13 | c.547G>T p.V183L | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0.014); catalogued as COSV101184311; called by muse, mutect2, varscan2
- IDH1 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs1553602798, COSV100577104; called by muse, mutect2, varscan2
- KIF4B | c.1472C>T p.A491V | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs200812701, COSV101469360; called by muse, mutect2, varscan2
- LRRFIP2 | c.2152C>G p.L718V | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs770285844, COSV99212548; called by muse, mutect2, varscan2
- NLRP2 | c.358G>A p.V120M | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs368936931; called by muse, mutect2, varscan2
- OASL | c.680G>A p.R227K | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.51); PolyPhen benign (0.097); catalogued as COSV99984602; called by muse, varscan2
- OR13C8 | c.871C>A p.L291I | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV58612754; called by muse, mutect2, varscan2
- PANX2 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.995); catalogued as rs1485043074, COSV50293248, COSV50308756; called by muse, mutect2, varscan2
- PER3 | c.3605G>C p.*1202Sext*21 | Nonstop Mutation (SNP) | VAF 25/109 reads (23%) | catalogued as COSV100648494; called by muse, mutect2, varscan2
- PLSCR4 | c.921G>A p.M307I | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as COSV100724284; called by muse, mutect2, varscan2
- SGIP1 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as rs1237484609, COSV99392254; called by muse, mutect2, varscan2
- SON | c.959C>G p.P320R | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV99279219; called by muse, mutect2, varscan2
- SPATA2 | c.262G>T p.A88S | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99192888; called by muse, mutect2, varscan2
- TAAR2 | c.572A>C p.Y191S (on ENST00000367931 / NM_001033080.1; = p.Y146S on NM_014626.3) | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99255719; called by muse, mutect2
- TFCP2L1 | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV55292590, COSV99748476; called by muse, mutect2, varscan2
- TTPA | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99478582; called by muse, mutect2
- VAX1 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV53329064, COSV53330049; called by muse, mutect2, varscan2
- WDR18 | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781748795; called by muse, mutect2, varscan2
- ZNF426 | c.251A>T p.Q84L | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV99465295; called by muse, mutect2, varscan2
- ZNF507 | c.916G>A p.V306I | Missense Mutation (SNP) | VAF 23/216 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.306); catalogued as rs1398005278, COSV100321993; called by muse, mutect2, varscan2
- ZSWIM4 | c.2384C>T p.A795V | Missense Mutation (SNP) | VAF 74/169 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.947); catalogued as rs768758572, COSV54321981; called by muse, mutect2, varscan2
- BTG2 | c.18_19insCA p.T7Qfs*19 | Frame Shift Ins (INS) | VAF 2/11 reads (18%) | called by muse*, mutect2
- GRK2 | c.178del p.S60Pfs*14 | Frame Shift Del (DEL) | VAF 50/188 reads (27%) | called by mutect2, pindel, varscan2
- IGHG3 | c.181G>C p.G61R | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LCAT | c.1018_1026del p.G340_G342del | In Frame Del (DEL) | VAF 38/166 reads (23%) | called by mutect2, pindel, varscan2
- MUC5AC | c.14129G>A p.G4710E | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NFAT5 | c.3735_3736del p.P1246Ifs*26 | Frame Shift Del (DEL) | VAF 14/84 reads (17%) | called by pindel, varscan2
- NOTCH1 | c.1140del p.C381Vfs*250 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | called by mutect2, pindel, varscan2
- PARP14 | c.1203delinsAT p.N401Kfs*4 | Frame Shift Ins (INS) | VAF 43/199 reads (22%) | called by pindel, varscan2*
- XKR3 | c.1235G>A p.R412H | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERF | c.312C>T p.Y104= | Silent (SNP) | VAF 31/185 reads (17%) | catalogued as COSV99724769; called by muse, mutect2, varscan2
- HHIPL2 | c.201C>T p.F67= | Silent (SNP) | VAF 26/70 reads (37%) | catalogued as rs777269842, COSV58563882; called by muse, mutect2, varscan2
- MED12L | c.2886T>C p.Y962= | Silent (SNP) | VAF 76/361 reads (21%) | catalogued as COSV99853966; called by muse, mutect2, varscan2
- NPAS3 | c.1587C>T p.D529= (on ENST00000356141 / NM_001164749.2; = p.D497= on NM_022123.3) | Silent (SNP) | VAF 31/81 reads (38%) | catalogued as rs148867285, COSV60832217; called by muse, mutect2, varscan2
- NTRK1 | c.1411T>C p.L471= | Silent (SNP) | VAF 17/99 reads (17%) | catalogued as rs369642315, COSV62324543; called by muse, mutect2, varscan2
- OR2M4 | c.619C>T p.L207= | Silent (SNP) | VAF 13/95 reads (14%) | catalogued as COSV100141410, COSV60708439; called by muse, mutect2, varscan2
- PSME4 | c.3981A>G p.S1327= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs761503218, COSV101122579; called by muse, mutect2, varscan2
- PTPRF | c.2616G>A p.K872= | Silent (SNP) | VAF 20/121 reads (17%) | catalogued as COSV100741065; called by muse, mutect2, varscan2
- PTPRM | c.639G>A p.V213= | Silent (SNP) | VAF 11/140 reads (8%) | catalogued as rs898359627, COSV100158961; called by muse, mutect2
- SFI1 | c.1332C>G p.A444= (on ENST00000400288 / NM_001007467.3; = p.A413= on NM_014775.4) | Silent (SNP) | VAF 68/194 reads (35%) | catalogued as COSV66291057; called by muse, mutect2, varscan2
- TMEM74B | c.354G>A p.P118= | Silent (SNP) | VAF 22/127 reads (17%) | catalogued as rs139413230; called by muse, mutect2, varscan2
- TNRC6B | c.2985C>T p.D995= (on ENST00000454349 / NM_001162501.2; = p.D942= on NM_015088.3) | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs750932350, COSV100110108; called by muse, mutect2
- TRAF3 | c.765C>T p.S255= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as rs779058785, COSV100693680; called by muse, mutect2, varscan2
- ZNF454 | c.9C>A p.V3= | Silent (SNP) | VAF 8/83 reads (10%) | catalogued as COSV100194671, COSV100195181; called by muse, mutect2, varscan2
- MACF1 | c.15832-8157G>A | Intron (SNP) | VAF 7/48 reads (15%) | catalogued as COSV99245752; called by muse, mutect2, varscan2
